Somatic mutation profile of tumor specimen TCGA-55-8614-01A (aliquot TCGA-55-8614-01A-11D-2393-08) from TCGA case TCGA-55-8614, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.5 years (27,924 days).
Specimen TCGA-55-8614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f48efa1-82c4-4d2d-9778-1db4ecea6234.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8614-10A (Blood Derived Normal), aliquot TCGA-55-8614-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07a4a7f-47d3-4049-a447-4307054bc24a

The open-access MAF lists 258 somatic variants for this specimen: 184 protein-altering or splice-affecting, 66 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 66, Nonsense Mutation 9, Splice Site 6, Frame Shift Del 5, RNA 3, Frame Shift Ins 3, 3'UTR 2, 5'Flank 2, In Frame Del 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKP2 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 89/336 reads (26%) | catalogued as rs760576804, CM118968, COSV99297496; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.1903-2A>G p.X635_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | catalogued as rs1326805521, COSV99446212; called by muse, mutect2, varscan2
- ACCSL | c.1295A>T p.Q432L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101122170; called by muse, mutect2, varscan2
- AGPAT4 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100211229, COSV57248272; called by muse, mutect2, varscan2
- AHNAK | c.14569G>C p.D4857H | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.204); catalogued as COSV99946760; called by muse, mutect2, varscan2
- ANKRD13A | c.1040T>A p.I347N | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99923900; called by muse, mutect2, varscan2
- ANKRD34A | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV100041202; called by muse, mutect2, varscan2
- ARHGAP33 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as rs535794132, COSV50121111; called by muse, mutect2
- BCL9 | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); catalogued as COSV99324852; called by muse, mutect2, varscan2
- BMPR2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101001402; called by muse, mutect2, varscan2
- BPIFC | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300937; called by muse, mutect2, varscan2
- C2CD3 | c.4752G>C p.Q1584H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV100486440; called by muse, mutect2, varscan2
- C3 | c.4484C>A p.P1495Q | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99836438; called by muse, mutect2, varscan2
- CCDC181 | c.1447G>C p.E483Q (on ENST00000367806 / NM_001300969.1; = p.E482Q on NM_021179.2) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs965903663, COSV100250480; called by muse, mutect2, varscan2
- CCDC181 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV63157389; called by muse, mutect2, varscan2
- CCDC7 | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV99511481; called by muse, mutect2, varscan2
- CDH1 | c.1940A>T p.Q647L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.419); catalogued as COSV99931663; called by muse, mutect2, varscan2
- CDH10 | c.1816C>G p.P606A | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.177); catalogued as COSV100050894, COSV52581136, COSV52592268; called by muse, mutect2
- CDH8 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV54854359, COSV54867192; called by muse, mutect2, varscan2
- CEP85L | c.1746-1G>C p.X582_splice | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100874173; called by muse, mutect2, varscan2
- CEP85L | c.1580A>G p.Q527R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100874174; called by muse, mutect2, varscan2
- CFAP61 | c.974C>A p.A325E | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.04); catalogued as COSV99844245; called by muse, mutect2, varscan2
- CHML | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 107/482 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100087235; called by muse, mutect2, varscan2
- CKS1B | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100460402; called by muse, mutect2, varscan2
- CNBD2 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.702); catalogued as COSV100839071; called by muse, mutect2
- COL16A1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375383196, COSV54712152; called by muse, mutect2, varscan2
- COL5A3 | c.2950G>A p.G984S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs866175122, COSV99318517; called by muse, mutect2, varscan2
- COL6A1 | c.2777T>G p.F926C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.67); catalogued as COSV100720092; called by muse, mutect2, varscan2
- CSMD3 | c.4831A>G p.S1611G (on ENST00000297405 / NM_001363185.1; = p.S1507G on NM_052900.3) | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.858); catalogued as COSV99830632; called by muse, mutect2, varscan2
- CTSZ | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as COSV99413511; called by muse, mutect2, varscan2
- DCAF11 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337704140; called by muse, mutect2
- DCAF4L2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs567814460, COSV100150690; called by muse, mutect2, varscan2
- DCUN1D2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100215077, COSV100215145, COSV60261272; called by muse, mutect2, varscan2
- DHX34 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100169439; called by muse, mutect2, varscan2
- DMRTC2 | c.224+2T>A p.X75_splice | Splice Site (SNP) | VAF 76/150 reads (51%) | catalogued as COSV99523351; called by muse, mutect2, varscan2
- DNAH7 | c.2490G>C p.K830N | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100414635; called by muse, mutect2, varscan2
- DNAH8 | c.3407T>C p.M1136T | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100544270; called by muse, mutect2, varscan2
- DOCK4 | c.2387C>G p.T796S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV101447823; called by mutect2, varscan2
- DPYSL5 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99982141; called by muse, mutect2
- DVL2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374072094; called by muse, mutect2, varscan2
- E2F7 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 24/196 reads (12%) | catalogued as COSV100523431; called by muse, mutect2, varscan2
- ECI2 | c.785C>T p.A262V (on ENST00000380118 / NM_206836.3; = p.A232V on NM_006117.2) | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100326408; called by muse, mutect2, varscan2
- EIF3E | c.145A>C p.N49H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV55207203, COSV99623011; called by muse, mutect2, varscan2
- ENOX1 | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99815603; called by muse, mutect2, varscan2
- EPHA5 | c.2359G>T p.G787* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV99078204, COSV99897942; called by muse, mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- EZH2 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV100235348; called by muse, mutect2, varscan2
- FAM47B | c.1804A>T p.R602* | Nonsense Mutation (SNP) | VAF 69/166 reads (42%) | catalogued as COSV100264232; called by muse, mutect2, varscan2
- FAT1 | c.7088T>C p.V2363A | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV101499252; called by muse, mutect2, varscan2
- FH | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs200412958, COSV100845004, COSV100845021; called by muse, mutect2, varscan2
- FHL3 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100885091; called by muse, mutect2, varscan2
- FNDC1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV51931046; called by muse, mutect2, varscan2
- FRMD3 | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100418512; called by muse, mutect2, varscan2
- GABRR2 | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV101298904; called by muse, mutect2, varscan2
- GAD2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99392993; called by muse, mutect2, varscan2
- GAK | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs771564068, COSV100033322; called by muse, mutect2, varscan2
- GALNT7 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | catalogued as rs1211486263, COSV53928615; called by muse, mutect2, varscan2
- GDAP2 | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV101031922; called by muse, mutect2, varscan2
- GJC1 | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100395149; called by muse, mutect2
- GP6 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs200525940; called by muse, mutect2, varscan2
- GPR83 | c.1009A>T p.S337C | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99703643; called by muse, mutect2, varscan2
- HEATR5B | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99248891; called by muse, mutect2, varscan2
- HELLS | c.80C>G p.T27S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV99491934; called by muse, mutect2, varscan2
- HNRNPM | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57695470; called by muse, mutect2, varscan2
- HTR4 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1015629322, COSV100087662; called by muse, mutect2, varscan2
- IFNE | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100438804; called by muse, mutect2, varscan2
- IFT122 | c.2003G>C p.R668T (on ENST00000348417 / NM_052989.3; = p.R609T on NM_018262.4) | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99959076; called by muse, mutect2
- IGKV1-5 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs982789043; called by muse, mutect2, varscan2
- IL18RAP | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as COSV51825271, COSV99961875; called by muse, mutect2, varscan2
- IL5 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs755418324, COSV99185045; called by muse, mutect2, varscan2
- ITCH | c.629C>A p.S210Y (on ENST00000262650 / NM_001257137.3; = p.S169Y on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV99392270; called by muse, mutect2, varscan2
- JAG2 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV100078120, COSV59307543; called by muse, mutect2, varscan2
- KALRN | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 58/353 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1204492703, COSV99563368; called by muse, mutect2, varscan2
- KCNJ10 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV100927903; called by muse, mutect2, varscan2
- KCNT1 | c.691G>A p.E231K (on ENST00000488444; = p.E250K on NM_020822.3) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV53709059; called by muse, mutect2, varscan2
- KIF1C | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100297052; called by muse, mutect2, varscan2
- KLHL1 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV100917135; called by muse, mutect2, varscan2
- KNDC1 | c.4744G>T p.A1582S | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100464251; called by muse, mutect2
- KRTAP10-5 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV100552747, COSV59976695; called by muse, mutect2, varscan2
- KRTAP10-5 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100552754, COSV59957473; called by muse, mutect2, varscan2
- L3MBTL3 | c.1508A>T p.H503L | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100695909; called by muse, mutect2
- L3MBTL4 | c.1446G>T p.V482= | Splice Region (SNP) | VAF 6/82 reads (7%) | catalogued as rs1373663498, COSV99528335; called by muse, mutect2
- LIFR | c.2443A>G p.T815A | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767895692, COSV99663830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIM2 | c.323C>G p.S108* (on ENST00000596399 / NM_001161748.2; = p.S150* on NM_030657.4) | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | catalogued as COSV99702308; called by muse, mutect2
- LMBRD1 | c.1345A>G p.M449V (on ENST00000649011; = p.M427V on NM_018368.4) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV100992522; called by muse, mutect2, varscan2
- LPAR3 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV101004729; called by muse, mutect2, varscan2
- LRP6 | c.4622A>C p.Y1541S | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); catalogued as COSV99742946; called by muse, mutect2, varscan2
- LRRIQ1 | c.4042G>C p.G1348R | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101279950, COSV67831912; called by muse, mutect2, varscan2
- LRRTM4 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV101297493; called by muse, mutect2, varscan2
- LRRTM4 | c.544A>T p.N182Y | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101297495; called by muse, mutect2, varscan2
- LSAMP | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.778); catalogued as rs117984283; called by muse, mutect2, varscan2
- LUC7L | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99551115; called by muse, mutect2, varscan2
- MAP2 | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52311429; called by muse, varscan2
- MCF2L2 | c.1987C>G p.Q663E | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as COSV100191985; called by muse, mutect2
- MMRN1 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV53333985, COSV99306872; called by muse, mutect2, varscan2
- MMRN1 | c.3172A>G p.N1058D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV53336734; called by muse, mutect2, varscan2
- MORC1 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225660; called by muse, mutect2, varscan2
- MRGBP | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs1568731875, COSV100978276; called by muse, mutect2
- MUC16 | c.16233C>A p.H5411Q | Missense Mutation (SNP) | VAF 138/480 reads (29%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.181); catalogued as COSV101199314; called by muse, mutect2, varscan2
- MUC17 | c.1606G>T p.V536F | Missense Mutation (SNP) | VAF 230/1001 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100072632; called by muse, mutect2, varscan2
- MUS81 | c.931del p.V311Wfs*46 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as COSV100337244; called by mutect2, pindel, varscan2
- MYO1G | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99348616; called by muse, mutect2, varscan2
- MYOCD | c.2048G>T p.C683F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.445); catalogued as COSV100590547; called by muse, mutect2, varscan2
- NCCRP1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs778747219, COSV100355777, COSV59212221; called by muse, mutect2, varscan2
- NCKAP5 | c.3799G>T p.G1267C | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491196; called by muse, mutect2
- NCOR2 | c.7126G>A p.A2376T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as rs773013649, COSV62295887; called by muse, mutect2, varscan2
- NCOR2 | c.412-2A>G p.X138_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100657136; called by muse, mutect2, varscan2
- NDST3 | c.1554G>C p.M518I | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99630128; called by muse, mutect2, varscan2
- NFASC | c.2155C>A p.R719S (on ENST00000339876 / NM_001378329.1; = p.R715S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV100363414, COSV58364310; called by muse, mutect2, varscan2
- NPHS1 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV62289868, COSV62290282; called by muse, mutect2, varscan2
- OPN4 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99618207; called by muse, mutect2
- OR14A16 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100713742; called by muse, mutect2, varscan2
- OR2A2 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV101286638; called by muse, mutect2, varscan2
- OR2G2 | c.806G>T p.R269I | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.222); catalogued as COSV100189688; called by muse, mutect2, varscan2
- OR2L8 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as COSV100594104; called by muse, mutect2, varscan2
- OR2T11 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100424756; called by muse, mutect2, varscan2
- OR3A2 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as rs373734930; called by muse, mutect2, varscan2
- OR4K2 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 137/337 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100064331; called by muse, mutect2, varscan2
- OR51V1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100343315; called by muse, varscan2
- OR6C74 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100667715; called by muse, mutect2, varscan2
- OR8B4 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as rs778477965, COSV62070624; called by muse, mutect2, varscan2
- PAM | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.602); catalogued as COSV104387597, COSV99173244; called by muse, mutect2, varscan2
- PCDH10 | c.2198T>A p.M733K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99993329; called by muse, mutect2, varscan2
- PCF11 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.629); catalogued as rs200011945, COSV53531272; called by muse, mutect2
- PCLO | c.5260C>G p.Q1754E | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100430318; called by muse, mutect2, varscan2
- PDE5A | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV99308569; called by muse, mutect2, varscan2
- PGAP2 | c.421A>G p.I141V (on ENST00000463452 / NM_001346398.2; = p.I202V on NM_014489.4) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.017); catalogued as COSV99544178; called by muse, mutect2, varscan2
- PIWIL3 | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201604636, COSV100177459; called by muse, mutect2, varscan2
- PLXNC1 | c.2237G>C p.G746A | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.609); catalogued as COSV99312842; called by muse, mutect2, varscan2
- PPM1B | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs773905065, COSV99175741; called by muse, mutect2, varscan2
- PRDM9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs112157044; called by muse, mutect2
- PSG5 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 40/666 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100742637; called by muse, mutect2
- PTPN13 | c.4575A>T p.Q1525H (on ENST00000411767 / NM_080683.3; = p.Q1506H on NM_006264.3) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100364509, COSV57404552; called by muse, mutect2, varscan2
- RPH3A | c.159G>T p.E53D (on ENST00000389385 / NM_001143854.2; = p.E49D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV101231798; called by muse, mutect2, varscan2
- SCN5A | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749651069, COSV61118544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5B | c.2920T>C p.W974R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560276687, COSV99531359; called by muse, mutect2, varscan2
- SIDT1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as COSV53504933; called by muse, mutect2, varscan2
- SIGLEC11 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs139706382, COSV101389251, COSV70222037; called by muse, mutect2, varscan2
- SLC7A10 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV99472147; called by muse, mutect2
- SLITRK2 | c.1124C>A p.T375N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV59427935; called by muse, mutect2, varscan2
- SMTN | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100294212; called by muse, mutect2
- SPHKAP | c.2716G>C p.D906H | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as COSV100763980, COSV60879063; called by muse, mutect2
- SPOCD1 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99929673; called by muse, mutect2
- SPRR1A | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs963794101, COSV100201027; called by muse, mutect2, varscan2
- SSTR3 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60729128, COSV60729224; called by muse, mutect2, varscan2
- STN1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.47); catalogued as rs780655414, COSV56546283, COSV99830345; called by muse, mutect2, varscan2
- STYK1 | c.553A>T p.T185S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.867); catalogued as COSV99311803; called by mutect2, varscan2
- TBX20 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.981); catalogued as COSV101282364; called by muse, mutect2, varscan2
- TCP11 | c.602G>A p.R201Q (on ENST00000512012; = p.R139Q on NM_018679.5) | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs778219246, COSV55134135; called by muse, mutect2, varscan2
- TIGD3 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV52888473, COSV99361499; called by muse, mutect2, varscan2
- TLE4 | c.2099A>T p.H700L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99511737; called by muse, mutect2, varscan2
- TMC3 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.164); catalogued as rs763575401, COSV100845878; called by mutect2, varscan2
- TMPRSS11B | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.141); catalogued as COSV100219307; called by muse, mutect2, varscan2
- TRAPPC8 | c.2915C>G p.P972R | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV99350931; called by muse, mutect2
- TRHDE | c.2441G>T p.R814L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.313); catalogued as COSV53849505, COSV53859966; called by muse, mutect2
- TRIO | c.6736G>T p.V2246L | Missense Mutation (SNP) | VAF 143/259 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100702510; called by muse, mutect2, varscan2
- TTN | c.23901G>T p.Q7967H (on ENST00000591111; = p.Q7040H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | PolyPhen benign (0.244); catalogued as COSV100604305; called by muse, mutect2, varscan2
- TTN | c.18576del p.I6193Lfs*36 (on ENST00000591111; = p.I5266Lfs*36 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV59906691; called by mutect2, pindel, varscan2
- UPB1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100387137; called by muse, mutect2, varscan2
- USH2A | c.8177G>C p.G2726A | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs549796389, COSV100232569; called by muse, mutect2, varscan2
- VPS36 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100955168; called by muse, mutect2, varscan2
- WAC | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100610960; called by muse, mutect2, varscan2
- WASF2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71005016; called by muse, mutect2, varscan2
- WASHC4 | c.2054G>T p.R685L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59890817; called by muse, mutect2, varscan2
- WDR7 | c.3521A>G p.H1174R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.888); catalogued as COSV99589155; called by muse, mutect2, varscan2
- WDR72 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100854343; called by muse, mutect2, varscan2
- ZBTB24 | c.1050C>A p.Y350* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100018391; called by muse, mutect2, varscan2
- ZBTB25 | c.546C>G p.D182E | Missense Mutation (SNP) | VAF 167/471 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101170712; called by muse, mutect2, varscan2
- ZFHX4 | c.8923G>T p.V2975L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99260942; called by muse, mutect2, varscan2
- ZMYND15 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99351182; called by muse, mutect2, varscan2
- ZNF761 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.898); catalogued as rs530162454, COSV100483325; called by muse, mutect2
- ZSCAN20 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63685301; called by muse, mutect2, varscan2
- ZSCAN4 | c.1205A>T p.K402M | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV99989888; called by muse, mutect2
- ZSWIM5 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100655483; called by muse, mutect2, varscan2
- ABHD17A | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- BTN2A1 | c.1296_1297delinsT p.A433Pfs*11 | Frame Shift Del (DEL) | VAF 29/163 reads (18%) | called by pindel, varscan2*
- COL6A2 | c.1182dup p.X394_splice | Splice Site (INS) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- FEM1B | c.970_971insATC p.A323_L324insH | In Frame Ins (INS) | VAF 30/133 reads (23%) | called by mutect2, pindel, varscan2
- HOXA5 | c.434dup p.A146Gfs*43 | Frame Shift Ins (INS) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- PKP4 | c.1734_1745del p.L579_R582del | In Frame Del (DEL) | VAF 13/105 reads (12%) | called by mutect2, pindel, varscan2
- RUNX1T1 | c.1301dup p.H434Qfs*17 (on ENST00000265814 / NM_001198628.1; = p.H407Qfs*17 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 43/245 reads (18%) | called by mutect2, pindel, varscan2
- TGM1 | c.2363dup p.A789Sfs*14 | Frame Shift Ins (INS) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- UTY | c.3883del p.S1295Afs*8 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel
- ABCA2 | c.1704G>A p.P568= (on ENST00000614293; = p.P538= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs373592462, COSV99687374; called by muse, mutect2, varscan2
- ABHD11 | c.72C>T p.L24= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99766775; called by muse, mutect2, varscan2
- ACTRT1 | c.426G>T p.V142= | Silent (SNP) | VAF 77/205 reads (38%) | catalogued as COSV100947545; called by muse, mutect2, varscan2
- ATN1 | c.1104G>C p.A368= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as COSV100755741, COSV63112208; called by muse, mutect2, varscan2
- BIN2 | c.438C>A p.L146= | Silent (SNP) | VAF 41/212 reads (19%) | catalogued as COSV99909307; called by muse, mutect2, varscan2
- BRWD3 | c.2397A>G p.T799= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100955898; called by muse, mutect2, varscan2
- CADM3 | c.1008C>T p.I336= (on ENST00000368125 / NM_001127173.3; = p.I370= on NM_021189.5) | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs767354987, COSV63675782; called by muse, mutect2, varscan2
- CD163L1 | c.3114A>G p.L1038= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100549924; called by muse, mutect2, varscan2
- CHAT | c.1047A>T p.P349= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV100339982; called by muse, mutect2, varscan2
- CLDN8 | c.315C>G p.T105= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99729784; called by mutect2, varscan2
- COBL | c.3360G>A p.A1120= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs887032675, COSV54352523; called by muse, mutect2, varscan2
- CYB5R4 | c.1152A>T p.I384= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100859653; called by muse, mutect2, varscan2
- DAD1 | c.156C>G p.P52= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV99164708; called by muse, mutect2, varscan2
- DDR1 | c.2211C>T p.T737= (on ENST00000324771; = p.T700= on NM_001954.4) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs372618092, COSV100241338; called by muse, mutect2, varscan2
- FBXL6 | c.1479G>T p.V493= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100095621; called by muse, mutect2, varscan2
- FGB | c.228C>T p.A76= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100122397; called by muse, mutect2
- FGD6 | c.312T>C p.D104= | Silent (SNP) | VAF 43/281 reads (15%) | catalogued as COSV100676491; called by muse, mutect2, varscan2
- FGF23 | c.699C>T p.N233= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs535885242, COSV99426356; called by muse, mutect2, varscan2
- FOXJ3 | c.264A>G p.T88= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV100691647; called by muse, mutect2, varscan2
- GALNTL6 | c.345T>C p.N115= | Silent (SNP) | VAF 52/219 reads (24%) | catalogued as rs190908476; called by muse, mutect2, varscan2
- GOLGB1 | c.6744A>G p.E2248= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV100510622; called by muse, mutect2, varscan2
- GRB10 | c.399A>G p.S133= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100240166; called by muse, mutect2, varscan2
- HCRTR1 | c.351C>T p.A117= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101036181; called by muse, mutect2, varscan2
- HERC2 | c.7140C>G p.L2380= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- HIVEP1 | c.3000C>T p.S1000= | Silent (SNP) | VAF 52/366 reads (14%) | catalogued as COSV101045038; called by muse, mutect2, varscan2
- HPGDS | c.294C>T p.F98= | Silent (SNP) | VAF 15/179 reads (8%) | catalogued as COSV99755599; called by muse, mutect2
- INSC | c.996C>T p.T332= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as rs199609375, COSV101088987; called by muse, mutect2, varscan2
- ITGA7 | c.3468G>T p.P1156= (on ENST00000555728; = p.P1112= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV57693538, COSV99145094; called by muse, mutect2, varscan2
- KCNB2 | c.2457A>C p.P819= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as COSV101578722; called by muse, mutect2, varscan2
- KCNH7 | c.1248G>T p.L416= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100035082; called by muse, mutect2, varscan2
- KIAA0586 | c.885A>G p.P295= (on ENST00000619416 / NM_001244190.2; = p.P310= on NM_014749.5) | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV99707852; called by muse, mutect2, varscan2
- KLHL1 | c.1768C>A p.R590= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100917134, COSV64787819; called by muse, mutect2
- LACTB2 | c.24C>T p.V8= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs148723423; called by muse, mutect2, varscan2
- LGMN | c.1146C>T p.A382= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV100605771; called by muse, mutect2, varscan2
- LRRC4B | c.882C>T p.H294= | Silent (SNP) | VAF 38/246 reads (15%) | catalogued as rs1167226591, COSV65349545; called by muse, mutect2, varscan2
- LRRTM4 | c.810G>T p.P270= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1403286163, COSV69138977, COSV69140387; called by mutect2, varscan2
- MBOAT7 | c.987G>T p.A329= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs376378590, COSV55477117, COSV99824744; called by muse, mutect2, varscan2
- MED12 | c.2223C>T p.P741= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1384811995, COSV100377192; called by muse, mutect2, varscan2
- MTO1 | c.1869A>G p.E623= (on ENST00000370300 / NM_133645.3; = p.E598= on NM_012123.4) | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100940392; called by muse, mutect2, varscan2
- NEB | c.9948T>C p.R3316= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as COSV99419426; called by muse, mutect2
- NOS1 | c.117G>T p.P39= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100500354; called by muse, mutect2, varscan2
- NR1H4 | c.369C>T p.R123= (on ENST00000551379 / NM_001206993.2; = p.R113= on NM_005123.4) | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs1399130415, COSV51857080, COSV99500350; called by muse, mutect2, varscan2
- NUP210 | c.4257C>T p.H1419= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV99595964; called by muse, mutect2, varscan2
- OGDHL | c.1890G>A p.A630= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs766441363, COSV65105550; called by muse, mutect2, varscan2
- OPRD1 | c.733C>T p.L245= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99330179; called by muse, mutect2, varscan2
- OR2L13 | c.288T>C p.C96= | Silent (SNP) | VAF 86/415 reads (21%) | catalogued as rs1343763818, COSV100813715; called by muse, mutect2, varscan2
- OR5H1 | c.609A>T p.S203= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100641666; called by muse, mutect2, varscan2
- OR8D1 | c.618C>T p.N206= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100766607; called by muse, mutect2, varscan2
- PANX3 | c.672C>T p.Y224= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99421401; called by muse, mutect2, varscan2
- PHOSPHO1 | c.645G>C p.A215= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99865418; called by muse, mutect2, varscan2
- PLCZ1 | c.744A>G p.L248= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV56852986, COSV99856173; called by muse, mutect2, varscan2
- POP1 | c.1038G>A p.A346= | Silent (SNP) | VAF 21/303 reads (7%) | catalogued as rs142413561; called by muse, mutect2
- RAD23A | c.873G>C p.L291= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100380056; called by muse, mutect2, varscan2
- RASGRF2 | c.1293C>T p.S431= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs746463883, COSV54141198; called by muse, mutect2, varscan2
- RBM12B | c.2883G>A p.E961= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV101234494; called by muse, mutect2, varscan2
- RNF31 | c.2463C>T p.H821= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as COSV100141683; called by muse, mutect2
- RXFP3 | c.606C>T p.C202= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs1485529081, COSV57505536; called by muse, mutect2, varscan2
- TLR5 | c.1585A>C p.R529= | Silent (SNP) | VAF 23/175 reads (13%) | catalogued as rs1379621564, COSV100643244; called by muse, mutect2, varscan2
- UTRN | c.7284A>G p.K2428= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100839781; called by muse, mutect2, varscan2
- VASP | c.231C>T p.P77= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV99840918; called by muse, mutect2, varscan2
- ZAN | c.2919G>A p.T973= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs1480446365, COSV61811969; called by muse, varscan2
- ZC3H3 | c.1848C>G p.L616= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV52794163, COSV99367667; called by muse, mutect2, varscan2
- ZFR | c.489A>G p.Q163= | Silent (SNP) | VAF 18/323 reads (6%) | catalogued as COSV99415667; called by muse, mutect2
- ZNF358 | c.1437C>A p.L479= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99900520; called by muse, mutect2
- ZNF687 | c.1968G>A p.P656= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs371085557, COSV55016984; called by muse, mutect2, varscan2
- ZNF710 | c.402G>T p.G134= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99184117; called by muse, mutect2, varscan2
- AMDHD2 | c.*870G>A | 3'UTR (SNP) | VAF 7/44 reads (16%) | catalogued as rs185302486, COSV99565826; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503828 A>G | 5'Flank (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- DCHS2 | n.2380G>T | RNA (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100251467; called by muse, varscan2
- HERC2P3 | n.1607G>A | RNA (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- HERC2P3 | chr15:20457882 G>T | 5'Flank (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- LEKR1 | c.*963A>G | 3'UTR (SNP) | VAF 31/72 reads (43%) | catalogued as COSV100738793; called by muse, mutect2, varscan2
- SNORD115-30 | n.61C>T | RNA (SNP) | VAF 38/307 reads (12%) | called by muse, mutect2, varscan2
- ZNF493 | c.-132+8514G>C | Intron (SNP) | VAF 27/148 reads (18%) | catalogued as rs1432324314, COSV100371966; called by muse, mutect2, varscan2
